Gene-level copy-number profile of tumor specimen TCGA-04-1516-01A from TCGA case TCGA-04-1516, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 48.6 years (17,768 days).
Specimen TCGA-04-1516-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.9cc09b82-8dd1-4e93-a49e-fef483c29709.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1516-11B (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0f40e0ae-a41b-4492-a2f0-ac46f350b920

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 71; copy number 1: 12,447; copy number 2: 22,725; copy number 3: 16,088; copy number 4: 5,390; copy number 5: 2,246; copy number 6: 809; copy number 7: 36.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-04-1516-01A-01D-1043-01): tumor purity 0.69, ploidy 2.44, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 71 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:155,829,729–162,985,416, 71 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,091 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:164,343,005–164,357,364, 3 genes, copy number 5: NMNAT1P2, RNU5F-6P, HMGB3P6.
- chr2:188,974,373–190,509,205, 31 genes, copy number 5 (within-gene range 4–5): COL3A1, MIR1245A, MIR1245B, MIR3606, COL5A2, AC133106.1, MIR3129, KRT18P19, WDR75, KDM3AP1, AC013439.1, SLC40A1, AC012488.1, ASNSD1, ASDURF, AC012488.2, ANKAR, OSGEPL1, OSGEPL1-AS1, AC013468.1, ORMDL1, PMS1, C2orf88, TERF1P6, HNRNPCP2, RNF11P1, MSTN, HIBCH, INPP1, MFSD6, AC093388.1.
- chr3:11,745–1,404,217, 15 genes, copy number 5 (within-gene range 3–5): LINC01986, AC066595.1, CHL1-AS2, AC066595.2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1, AC087428.1, LINC01266, RPSAP32, AC090044.1, AC087430.1, RN7SL120P, CNTN6.
- chr3:10,566,255–11,912,313, 25 genes, copy number 5: ATP2B2-IT1, ATP2B2-IT2, LINC00606, AC018495.1, SLC6A11, AC027128.1, SLC6A1, SLC6A1-AS1, AC066580.1, HRH1, AC083855.2, CHCHD4P4, ATG7, AC083855.1, AC026185.1, AC022001.1, VGLL4, AC022001.2, AC022001.3, TAMM41, FANCD2P2, CYCSP12, NUP210P2, MARK2P14, AC090958.1.
- chr3:38,845,764–41,260,096, 56 genes, copy number 5 (within-gene range 4–5): SCN11A, RNU6-1227P, WDR48, GORASP1, TTC21A, MIR6822, CSRNP1, AC092053.3, AC092053.2, Metazoa_SRP, AC092053.4, XIRP1, AC092053.6, DSTNP4, AC092053.5, CX3CR1, AC092053.1, AC104850.2, CCR8, HNRNPA1P21, AC104850.1, EEF1A1P24, SLC25A38, RPSA, SNORA6, SNORA62, AC099332.2, AC099332.1, MOBP, AC092058.1, NFU1P1, MYRIP, RNU4-56P, EIF1B-AS1, RN7SL411P, AC099331.1, EIF1B, ENTPD3-AS1, PGAM1P3, ENTPD3, RPL14, ZNF619, ZNF620, RNU5B-2P, ZNF621, RPL5P10, EEF1GP3, AC122683.1, HMGN2P24, AC099560.1, AC099560.2, AC099541.2, AC099541.1, AC009743.1, MRPS31P1, CTNNB1.
- chr3:69,591,341–94,507,620, 203 genes, copy number 5 (broad region; genes not listed).
- chr3:140,449,435–172,725,038, 496 genes, copy number 5 (broad region; genes not listed).
- chr5:176,905,005–180,072,113, 116 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:130,380,339–159,233,377, 663 genes, copy number 5–7 (broad region; genes not listed).
- chr9:14,475–19,464,524, 251 genes, copy number 5–7 (broad region; genes not listed).
- chr11:75,069,243–77,026,797, 64 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:10,226,058–39,619,803, 497 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr14:49,927,571–50,105,043, 1 gene, copy number 7 (within-gene range 4–7): LINC01588.
- chr14:50,050,368–51,096,061, 35 genes, copy number 5–7: PDLIM1P1, AL117692.1, RN7SKP193, Y_RNA, VCPKMT, SOS2, L2HGDH, MIR4504, DMAC2L, AL359397.2, CDKL1, AL359397.1, MAP4K5, AL118556.1, Y_RNA, AL118556.2, ATL1, SNRPGP1, SAV1, RN7SL452P, AL606834.1, ZFP64P1, NIN, AL606834.2, AL133485.2, AL133485.3, AL133485.1, AL358334.1, PYGL, ABHD12B, AL358334.3, AL358334.2, TRIM9, AL358334.4, AL591770.1.
- chr19:13,206,442–32,485,895, 632 genes, copy number 5–6 (within-gene range 1–6) (broad region; genes not listed).
- chr21:39,727,755–39,929,397, 3 genes, copy number 7 (within-gene range 4–7): AF064860.2, IGSF5, PCP4.

Autosomal genes at a single copy (total copy number 1): 10,378. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
